Gene-level copy-number profile of tumor specimen C3N-04279-01 from CPTAC case C3N-04279, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 65.8 years (24,049 days).
Specimen C3N-04279-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 85567e25-69ab-43e5-8ba3-2f418239078a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04279-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/f3268216-29a0-4238-ab1a-03a137cdba83

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 664; copy number 1: 11,762; copy number 2: 41,358; copy number 3: 4,080; copy number 4: 770; copy number 5: 124; copy number 6: 32; copy number 7: 42; copy number 9: 14; copy number 11: 12; copy number 12: 40; copy number 17: 11.

Homozygous deletions (total copy number 0; autosomes only): 151 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,589,529, 12 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr9:42,183,659–42,569,353, 12 genes: SPATA31A6, AL445584.1, FAM74A7, AL445584.3, AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1.
- chr9:43,109,866–60,964,196, 8 genes: FP325317.1, FP325317.2, BX088702.1, SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr21:9,068,361–9,129,752, 3 genes (within-gene range 0–1): TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:14,582,202–23,968,747, 116 genes (within-gene range 0–1) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 275 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,898,805–61,945,136, 2 genes, copy number 5–6: FAM242E, CR769775.1.
- chr11:66,393,449–70,436,584, 164 genes, copy number 5–17 (broad region; genes not listed).
- chr14:22,123,318–22,644,352, 99 genes, copy number 5 (broad region; genes not listed).
- chr22:41,551,710–41,698,136, 10 genes, copy number 5: AL023553.1, CSDC2, PMM1, DESI1, XRCC6, Y_RNA, SNU13, Z83840.1, RNU6-476P, C22orf46.

Autosomal genes at a single copy (total copy number 1): 9,429. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
